Somatic mutation profile of tumor specimen HCM-BROD-0871-C49-06B (aliquot HCM-BROD-0871-C49-06B-01D-A881-36) from HCMI case HCM-BROD-0871-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.7 years (22,167 days).
Specimen HCM-BROD-0871-C49-06B: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cbaacfd-1a20-4115-bebd-b70bca7ea83f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0871-C49-11A (Solid Tissue Normal), aliquot HCM-BROD-0871-C49-11A-11D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b36321b-ebe2-4b69-a314-b9e1601c8e4c

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 157/187 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSA | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 212/608 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.033); catalogued as rs1445271917; called by muse, mutect2, varscan2
- CALCR | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 126/287 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs146344939, COSV100810525; called by muse, mutect2, varscan2
- GLRB | c.1368C>G p.N456K | Missense Mutation (SNP) | VAF 212/424 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.098); catalogued as rs747170836; called by muse, mutect2, varscan2
- INHBB | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 243/548 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1303161649; called by muse, mutect2, varscan2
- ITGA6 | c.1945G>C p.D649H (on ENST00000442250; = p.D610H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99904994; called by muse, varscan2
- KLRG2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765088717, COSV100572614; called by muse, mutect2, varscan2
- KRT77 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs377759755; called by muse, mutect2
- MYH2 | c.5624A>G p.D1875G | Missense Mutation (SNP) | VAF 121/276 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1364758773; called by muse, mutect2, varscan2
- MYO9A | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs148826761; called by muse, mutect2, varscan2
- NEURL4 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 227/264 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs190339983; called by muse, mutect2, varscan2
- NPHP1 | c.1646T>A p.L549H (on ENST00000393272 / NM_207181.4; = p.L550H on NM_000272.5) | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57210359; called by muse, mutect2, varscan2
- RAPSN | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 161/387 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs148600999; called by muse, mutect2, varscan2
- SCAND1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs776778597; called by muse, mutect2, varscan2
- SDR16C5 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 118/285 reads (41%) | catalogued as COSV58125353; called by muse, mutect2, varscan2
- SPEN | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 115/287 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs138355680; called by muse, mutect2, varscan2
- ABCA1 | c.3188T>G p.V1063G | Missense Mutation (SNP) | VAF 139/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC069544.2 | c.634A>G p.S212G | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ADAMTS13 | c.3716-1G>C p.X1239_splice | Splice Site (SNP) | VAF 128/289 reads (44%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 245/482 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARFGAP2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 183/453 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ARHGEF39 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 145/292 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CENPJ | c.764del p.T255Ifs*25 | Frame Shift Del (DEL) | VAF 112/305 reads (37%) | called by mutect2, pindel, varscan2
- DSG2 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- FYB2 | c.1800A>C p.E600D | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- HBG1 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 251/323 reads (78%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IL15 | c.361A>T p.S121C | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LIN54 | c.1213_1214del p.P405Nfs*25 | Frame Shift Del (DEL) | VAF 106/304 reads (35%) | called by mutect2, pindel, varscan2
- MEIOC | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 137/319 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NRG1 | c.1700G>T p.S567I (on ENST00000405005 / NM_013964.5; = p.S572I on NM_013956.5) | Missense Mutation (SNP) | VAF 185/423 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- P2RY13 | c.48+1G>A p.X16_splice | Splice Site (SNP) | VAF 95/241 reads (39%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 175/339 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POFUT2 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 156/359 reads (43%) | called by muse, mutect2, varscan2
- PRR29 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 184/392 reads (47%) | called by muse, varscan2
- RNF113A | c.823A>T p.T275S | Missense Mutation (SNP) | VAF 211/233 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNPEPL1 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 184/396 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TMEM30B | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 244/280 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TPMT | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 145/166 reads (87%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- VWA3B | c.3158-1G>T p.X1053_splice | Splice Site (SNP) | VAF 133/280 reads (48%) | called by muse, mutect2, varscan2
- ZNF668 | c.1508A>T p.E503V | Missense Mutation (SNP) | VAF 267/575 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCN3 | c.117C>T p.C39= | Silent (SNP) | VAF 248/534 reads (46%) | catalogued as rs764279785, COSV52383385; called by muse, mutect2, varscan2
- FOXD3 | c.1053C>G p.A351= | Silent (SNP) | VAF 197/489 reads (40%) | called by muse, mutect2, varscan2
- NTF4 | c.72C>G p.S24= | Silent (SNP) | VAF 182/391 reads (47%) | called by muse, mutect2, varscan2
- PSD3 | c.282C>A p.V94= | Silent (SNP) | VAF 191/380 reads (50%) | called by mutect2, varscan2
- SLC18A1 | c.1281G>C p.G427= | Silent (SNP) | VAF 185/384 reads (48%) | catalogued as rs536694184; called by muse, mutect2, varscan2
- SYTL1 | c.78T>C p.P26= | Silent (SNP) | VAF 207/447 reads (46%) | called by muse, mutect2, varscan2
- WDR19 | c.1044C>G p.T348= | Silent (SNP) | VAF 148/344 reads (43%) | catalogued as COSV99975025; called by muse, mutect2, varscan2
- ZNF215 | c.696A>G p.P232= | Silent (SNP) | VAF 81/180 reads (45%) | called by muse, mutect2, varscan2
- ZNF708 | c.297A>C p.I99= | Silent (SNP) | VAF 115/267 reads (43%) | called by muse, mutect2, varscan2
- ATXN2L | c.*133C>T | 3'UTR (SNP) | VAF 237/532 reads (45%) | catalogued as rs1347842613, COSV100295070, COSV57380381; called by muse, mutect2, varscan2
- KLC2 | c.*343C>G | 3'UTR (SNP) | VAF 212/470 reads (45%) | catalogued as rs1182338298; called by muse, mutect2, varscan2
- TPK1 | c.185+15091C>T | Intron (SNP) | VAF 142/354 reads (40%) | called by muse, mutect2, varscan2
